Somatic mutation profile of tumor specimen TCGA-OR-A5L1-01A (aliquot TCGA-OR-A5L1-01A-11D-A30A-10) from TCGA case TCGA-OR-A5L1, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 37.9 years (13,840 days).
Specimen TCGA-OR-A5L1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90efed25-3403-4bad-9fa5-4efb330388e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L1-10A (Blood Derived Normal), aliquot TCGA-OR-A5L1-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0d7d3a4-8465-4db9-ba65-40e4d84b0558

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 10, Silent 8, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 41/125 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CPNE3 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs781021543, COSV52211311; called by muse, mutect2, varscan2
- GTSF1 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs767605251; called by muse, mutect2, varscan2
- KCNA6 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV54974531; called by muse, mutect2, varscan2
- BCL7B | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NWD1 | c.1697T>A p.L566H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCDHA9 | c.2382T>G p.D794E | Missense Mutation (SNP) | VAF 146/318 reads (46%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A11 | c.1642_1665del p.L548_S555del | In Frame Del (DEL) | VAF 50/140 reads (36%) | called by mutect2, varscan2
- SPATA31E1 | c.1068C>A p.F356L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TBCB | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VCX3A | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC12 | c.288A>C p.S96= | Silent (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- FBXW12 | c.610C>T p.L204= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99601725; called by muse, mutect2, varscan2
- MKLN1 | c.678A>G p.E226= | Silent (SNP) | VAF 40/136 reads (29%) | called by muse, varscan2
- OR11H12 | c.903T>C p.N301= | Silent (SNP) | VAF 48/254 reads (19%) | called by muse, varscan2
- PBX3 | c.1029C>T p.N343= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- PGLYRP4 | c.846C>T p.G282= | Silent (SNP) | VAF 52/59 reads (88%) | catalogued as rs184556258; called by muse, mutect2, varscan2
- TAAR5 | c.669T>C p.F223= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- TDRD1 | c.2985C>T p.D995= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs767859168, COSV99314102; called by mutect2, varscan2
